Surgical pathology report (de-identified scan), TCGA case TCGA-WC-AA9A, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-AA9A-01A (Primary Tumor).

Accession:
Specimen Date/Time:

DIAGNOSIS

- (A) RIGHT GLOBE, ENUCLEATION:
CHOROIDAL MELANOMA, 14 MM BASE, SPINDLED TYPE.
SUPERFICIAL SCLERAL INVASION PRESENT.
Optic nerve invasion is not identified.
Vortex vein is negative for tumor.
Extraocular extension is not identified. (See Comment)

COMMENT

The tumor shows mitotic activity at 3 per 10 high-power fields. A PAS is examined to review the internal ocular structures.

GROSS DESCRIPTION

(A) RIGHT EYE – An enucleation specimen consisting of an intact globe (23 x 23 x 22 mm) has an attached optic nerve 5 mm in length. The sclera is unremarkable. The anterior chamber is formed by a gray-blue iris (10 x 11 mm) which surrounds a round 5 mm pupil. The anterior chamber appears clear. By transillumination a shadow is present from 7-11 o'clock with an approximate base of (14 x 14 mm). The shadow corresponds to a choroidal based mass with a height of 6 mm. The tumor is tan to dark brown and appears confined to the globe. The tumor is 3 mm from the optic nerve and 9 mm from the limbus. The vitreous is clear. Tumor harvest is performed, and the specimen is sectioned in a standard fashion.

SECTION CODE: A1-A4, vortex veins (superior temporal, superior nasal, inferior nasal, inferior temporal); A5, pupil-optic nerve section with tumor; A6, calotte with tumor; A7, remaining calotte; A8, optic nerve margin and additional portion of tumor.

CLINICAL HISTORY

Choroidal melanoma.

SNOMED CODES

T-AA000, M-87203

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 434ed098-9db0-460a-bf14-ce7c112ece20 (TCGA-WC-AA9A.A910FE6E-4D5B-43F9-88D9-679147FEA50F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).